Somatic mutation profile of tumor specimen 0E0A0H from CCDI case PBCTJR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.9 years (1,793 days).
Specimen 0E0A0H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdbf65be-18a9-47d7-8b0c-be52fa8962fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZY66 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14c6f405-2cae-4b34-9fd9-38838e961d4f

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYT4 | c.874C>T p.L292= | Silent (SNP) | VAF 62/2338 reads (3%) | called by muse, mutect2
- RAB34 | c.146+11G>A | Intron (SNP) | VAF 41/729 reads (6%) | called by muse, mutect2
